Surgical pathology report (de-identified scan), TCGA case TCGA-HZ-7289, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HZ-7289-01A (Primary Tumor).

[page 1 of 5]
Collection Date: [REDACTED]
Hospital of Origin:
Copy to:

TCCA-HZ-7289

QC Pathologist:

FINAL PATHOLOGIC DIAGNOSIS:

A. Omental implant; excision:

Benign fibroconnective and fibroadipose tissue, no evidence of carcinoma.

Intra-operative consultation corroborated.

B. Gallbladder; cholecystectomy:

Chronic cholecystitis.

Cholelithiasis.

No tumor identified.

C. Gastroepiploic lymph node; excision:

Benign fibroadipose tissue with acute inflammation and fat necrosis, no lymph node identified.

D. Celiac lymph node; excision:

Peripheral nerve and fibroconnective tissue, no lymph node identified.

Intra-operative consultation corroborated.

E. Lower pancreatic neck; excision:

Fibrotic stroma with entrapped pancreatic ductal structures, no evidence of malignancy.

F. Upper pancreatic neck; excision:

Atypical glandular epithelium suspicious for invasive well differentiated adenocarcinoma.

G. Duodenum, pancreas; full resection:

Tumor Characteristics:

1. Histologic type: Adenocarcinoma arising in the background of intraductal papillary mucinous neoplasm.
2. Histologic grade: Well differentiated.
3. Tumor site: Pancreatic head.
4. Tumor size: At least 4.5 cm.
5. Microscopic extent of tumor: Tumor extends into the duodenal wall.
6. Lymphovascular space invasion: Not identified in the sections submitted, see lymph node status below.
7. Perineural invasion: Focally present.
8. Treatment effect: Not identified.

Surgical Margin Status:

See comment for discussion of margins.

Lymph Node Status:

1. Total number of lymph nodes examined: Nine.

11.

[page 2 of 5]
2. Total number of lymph nodes containing metastatic carcinoma: One (1/9).

Other:

1. Accessory spleen with no significant histopathologic abnormality.
2. pTNM stage: pT3 N1.
3. Expert consultation pending, results to be reported as an addendum.

COMMENTS:

Histologic sections show a large mucinous neoplasm within the main pancreatic duct. The lesion produced abundant mucin which extravasated into the surrounding parenchyma. In addition there are areas which show cytologically bland but invasive glands within the pancreatic stroma. Focal areas are suspicious for perineural invasion. One lymph node also shows small cytologically bland glands consistent with tumor. These findings are supportive of a diagnosis of invasive carcinoma within the background of an IPMN. Specimens E and F represent the pancreatic neck margin according to Dr. [REDACTED]. Specimen F shows atypical glands suspicious for well differentiated adenocarcinoma. However the pancreatic neck margin (G1) shaved from the main resection shows fibrotic lobules without definitive carcinoma. Sections from the common bile duct (G4) and uncinate (G2) examined at frozen also show atypical glands. The proximal and distal duodenal margins are negative for tumor. The soft tissue pancreatic margins are also negative but are close (within 1 mm) of the superior, inferior, posterior and anterior. Because of the nature of the case, it will be sent to the [REDACTED] clinic for expert consultation. Results will be reported as an addendum.

These findings were discussed with Dr. [REDACTED] on [REDACTED].

CLINICAL HISTORY:

Preoperative Diagnosis: [REDACTED] year old [REDACTED] male, intraductal papillary mucinous tumor.

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Omental implant, rule out cancer, with frozen section
- B. Gallbladder
- C. Gastroepiploic lymph node
- D. Celiac lymph node with frozen section
- E. Lower pancreatic neck with frozen section
- F. Upper pancreatic neck with frozen section
- G. Duodenum, pancreas

TCGA-H2-7289

[page 3 of 5]
TCGA-HZ-7289

PROCEDURAL DEMOGRAPHICS:

Date of Procedure: [REDACTED]

Accession Date/Time: [REDACTED]

GROSS DESCRIPTION:

The specimen is received in seven containers labeled with the patient's name,

Container A is additionally labeled "omental implant," and contains a 1.0 cm yellow-tan, fibrofatty soft tissue. The specimen is entirely submitted for frozen section, with the residual entirely resubmitted for permanent section in cassette A, labeled

Container B is additionally labeled "gallbladder," and contains an 8.5 x 4.8 x 4.0 cm, intact gallbladder. The serosa is purple-pink and glistening. The lumen contains yellow-tan viscid bile along with multiple gray-green, multifaceted choleliths aggregating to 6.0 x 4.5 x 2.0 cm. The wall averages 0.2 cm in thickness. The mucosa is yellow-tan, smooth to roughened, with no excrescences or exophytic lesions. Representative sections are submitted in cassette B, labeled

Container C is additionally labeled "gastroepiploic lymph node," and contains a 4.5 x 2.0 x 1.0 cm, yellow-tan, fibrofatty soft tissue. On sectioning and palpation, suture material is identified, however, a discrete lymph node is not palpated. The specimen is entirely submitted in cassettes C1-3, labeled , for possible lymph node capture.

Container D is additionally labeled "celiac lymph node," and contains a 0.9 x 0.7 x 0.5 cm, yellow-gray, rubbery soft tissue entirely submitted for frozen section, with the residual entirely resubmitted for permanent section in cassette D, labeled

Container E is additionally labeled "lower pancreatic neck," and contains a 1.5 x 0.7 x 0.3 cm, yellow-tan, soft tissue. The specimen is entirely submitted for frozen section with the residual entirely resubmitted for permanent section in cassette E, labeled

Container F is additionally labeled, "upper pancreatic neck," and contains a 1.4 x 1.0 x 0.3 cm, gray-white, rubbery soft tissue entirely submitted for frozen section with the residual entirely resubmitted for permanent section in cassette F, labeled

Container G is additionally labeled, "duodenum, pancreas," and contains a Whipple resection specimen comprised of duodenum (16.5 cm in length and ranging from 3.5 up to 5.0

[page 4 of 5]
cm in diameter), pancreatic head (5.5 x 6.0 x 6.0 cm), and common bile duct (1.0 cm in length by 0.5 cm in diameter). The duodenal serosa is tan-gray and shaggy, with scant amounts of adherent yellow-tan mesenteric fat. On opening, the wall averages 0.9 cm in thickness. Two ampulla are identified. Surrounding the pancreatic ampulla is a 4.5 x 4.0 x 2.0 cm, pink-tan, papillary mucoid mass that approaches to within 2.0 cm of the inked proximal duodenal margin. On sectioning, pink tan mucoid and papillary tumor is present within the main pancreatic duct and approaches to within 0.2 cm of the pancreatic neck margin. Additionally, this mass approaches to within 0.1 cm of the inked pancreatic margin at the superior, inferior, anterior and posterior surfaces. The second ampulla is located 1.0 cm from the first. It is dilated to 1.5 cm in diameter and extrudes mucoid debris upon compression. This communicates with the common bile duct which contains abundant mucoid debris on sectioning. The remainder of the pancreatic parenchyma is gray-white, firm and fibrous. No normal-appearing pancreatic parenchyma is identified. On sectioning and palpation, multiple ill-defined firm nodules are identified along the periphery of the pancreas. These are possibly consistent with lymph nodes. They range from 0.2 up to 2.5 cm in greatest dimension. Representative sections are submitted for frozen section, with the residual entirely submitted for permanent section in cassettes G1-4, labeled _____ designated as follows: G1, pancreatic neck, previously designated FSG1; G2, uncinate, previously designated FSG2; G3, duodenum, previously designated FSG3; 4, common duct, previously designated FSG4. Additional representative sections are submitted in cassettes G5-20, designated as follows: G5, proximal duodenum and pancreas, perpendicular; G6, pancreatic ampulla; G7-9, protruding duodenal mass; G10, mass to inked superior pancreatic margin; G11, mass to inked inferior pancreatic margin, perpendicular; G12, mass to inked anterior pancreatic margin, perpendicular; G13, mass to inked posterior pancreatic margin, perpendicular; G14, common bile duct ampulla; G15, distal duodenum, en face; G16, five whole possible lymph nodes; G17-18, six whole possible lymph nodes in each cassette; G19-20, one whole possible bisected lymph node. Additionally, a yellow and a green cassette are submitted for genomics research labeled _____

INTRA-PROCEDURE CONSULTATION:

FROZEN SECTION DIAGNOSES:

FSA. "Negative for malignancy, benign fibroadipose tissue with fibrosis. Results given to _____ after positive patient ID," per Dr. _____

FSB. "Neural tissue, no tumor seen. Results to Dr _____ after positive patient ID," per I _____

TCCA-117-7289

[page 5 of 5]
FSE. "Extensive fibrosis. Result" Dr. after
positive patient ID," per Dr.

FSE. "Extensive fibrosis, no evidence of IPMT. Results to
[REDACTED] after positive patient ID," per Drs.

TCGA-42-7289

FSG1. "Pancreatic neck, fibrosis tumor not definitively
seen. Results to Dr.

FSG2. "Uncinate, fibrosis, tumor not definitively seen.
Results to Dr. after positive patient ID," per

FSG3. "Duodenum, negative. Results to Dr. after
positive patient ID," per Dr.

FSG4. "Common duct, fibrosis, tumor not definitively seen.
Results to Dr. after positive patient ID," per Dr.

XR Chest - PA and Lateral
Routine Exam

EXAMINATION: CHEST-PA & LATERAL
[REDACTED]

FULL RESULT:

Indication: Presurgical testing.

Two views of the chest were obtained.

Findings:

Heart size is normal. The lungs are hyperinflated consistent COPD. No
infiltrates or effusions are identified.

IMPRESSION:

Moderate COPD.

[REDACTED]
Cancer Antigen 19-9.

Cancer Antigen 19-9

331

H

[<37 U/ML]

1 or more Final Results Received
[REDACTED]

Source: NCI Genomic Data Commons file 85da6e45-26b5-41d2-82a9-88868bfae877 (TCGA-HZ-7289.477A4B9A-9BB9-42F5-9F96-1848974BB3AC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).